CCDI case PBCCST — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1a7d0f3b-8bb4-43ce-a0f8-0f47953ef7ee

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,869 days).

Biospecimens (3 samples)
- Sample 0DON4U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DON4Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DON56: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
